Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1YE, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1YE-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY

100-0-3
Carcinoma, papillary, follicular variant
Site: Thyroid, NOS C73.9
8340/3
3/6/11 *lw*

Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Service:

Visit #:

Accession #:

Collected:

Received:

Gender: F

Location:

Reported:

HCN:

Facility:

Ordering

MD:

Copy To:

Specimen(s) Received

1. Parathyroid: ? Parathyroid
2. Thyroid: Total - stitch marks upper pole right lobe (fresh for tissue banking)

Diagnosis

1. No pathological diagnosis: Parathyroid, 1, (site not specified) biopsy
2. Papillary carcinoma, 3.0 cm, right, underlying focal mild chronic inflammation and mild nodular hyperplasia: Thyroid
No pathological diagnosis: Lymph nodes, 3
-Total thyroidectomy specimen

Synoptic Data

Specimen Type:	Total Thyroidectomy
Tumour Focality:	Unifocal
Histologic Type:	Papillary carcinoma, follicular variant
Tumour Site:	Right Lobe
Tumour Size:	Greatest Dimension: 3.0 cm Additional Dimensions: 2.5 x 2.0 cm
Capsular Invasion:	Encapsulated
Extrathyroidal Extension:	Absent
Margins:	Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Pathologic Staging (pTNM):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 3 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings:	Nodular hyperplasia Thyroiditis

UUID: 3CE17C59-3SDE-4A7C-9B98-49444756D588

by:

Electronically verified

MD

[page 2 of 2]
Gross Description

1. The specimen labelled with the patient's name and as "Parathyroid: Query parathyroid" consists of a piece of tan tissue that weighs 0.003 g and measures 0.2 cm. It is frozen for intraoperative consultation.
1A- frozen section block resubmitted.

2. The specimen labeled with the patient's name and as "Thyroid: Total-stitch marks upper pole right lobe (fresh for tissue banking)" consists of a thyroid gland that is oriented with a stitch and weighs 19.6 g. The right lobe measures 5.0 cm SI x 2.3 cm ML x 1.5 cm AP, the left lobe measures 3.7 cm SI x 2.3 cm ML x 1.2 cm AP and the isthmus measures 2.0 cm SI x 1.7 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. The upper to mid right lobe contains a well-delineated solid nodule that measures 3.0 x 2.5 x 2.0 cm. The remainder of the thyroid tissue is grossly unremarkable. Sections of right lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

2A-F- right lobe, superior to inferior

2G-H- isthmus

2I-M- left lobe, superior to inferior

Quick Section Diagnosis

1.? Parathyroid – 1A: Parathyroid tissue present called at

MD

Source: NCI Genomic Data Commons file 4fe14cc1-f957-45b0-b6e7-1eb3afcce0d2 (TCGA-EM-A1YE.3CE17C59-35DE-4A7C-9B98-49444756D588.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).